MMRF case MMRF_2190 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cb7bced1-ef63-41fe-be61-e2922571c621

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.9 years (20,067 days); ISS stage: I; Days to last known disease status: 819 days (2.2 years); Days to last follow up: 819 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 108 days; Days to treatment end: 108 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 2.68 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.94 µg/mL; Lactate Dehydrogenase 12 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 3.96 mmol/L; C-Reactive Protein 0.573 mg/dL.
- Day 77 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 170 (ECOG 1): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 252 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 7.42 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 4.68 mmol/L.
- Day 364 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 420 (ECOG 1): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 4.29 mmol/L.
- Day 539 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.
- Day 630: M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 700: M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 819 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL.

Other clinical attributes
- Day -6: Weight: 80 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2190_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2190_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
